Somatic mutation profile of tumor specimen 0DL0JB from CCDI case PBBYSB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,963 days).
Specimen 0DL0JB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e21335b-5826-4d8d-b9e6-a2efc4ccf6a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b1d65f0-84ff-458b-ac5c-8004d59dd5f2

The open-access MAF lists 29 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, 3'UTR 2, Intron 2, 5'UTR 2, Splice Region 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRD9 | c.1646A>G p.N549S | Missense Mutation (SNP) | VAF 437/991 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs376872952; called by muse, mutect2, varscan2
- CABLES2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 291/719 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs776946463, COSV54159079; called by muse, mutect2, varscan2
- PACSIN2 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 447/972 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1281268602; called by muse, mutect2, varscan2
- SOWAHD | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 449/863 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as rs903993581; called by muse, mutect2, varscan2
- CMTM2 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 314/706 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- DDX3X | c.1501_1503del p.A501del (on ENST00000399959; = p.A502del on NM_001356.5) | In Frame Del (DEL) | VAF 278/646 reads (43%) | called by pindel, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 44/1478 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- MLLT10 | c.1057_1077del p.X353_splice | Splice Site (DEL) | VAF 101/220 reads (46%) | called by mutect2, pindel*, varscan2
- NUP50 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 166/692 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- PTCH1 | c.262_265del p.F88Nfs*28 | Frame Shift Del (DEL) | VAF 771/836 reads (92%) | called by mutect2, pindel, varscan2
- SEMA4F | c.819T>G p.C273W | Missense Mutation (SNP) | VAF 255/630 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.142A>G p.M48V | Missense Mutation (SNP) | VAF 454/1027 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TTC12 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 404/818 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- XPO1 | c.639+3_639+6del | Splice Region (DEL) | VAF 324/825 reads (39%) | called by mutect2, pindel, varscan2
- CDH3 | c.558C>T p.H186= | Silent (SNP) | VAF 268/598 reads (45%) | catalogued as rs775627086, COSV50560383; called by muse, mutect2
- HSPB6 | c.465G>A p.P155= | Silent (SNP) | VAF 264/579 reads (46%) | called by muse, varscan2
- IGSF10 | c.774C>T p.C258= | Silent (SNP) | VAF 397/940 reads (42%) | called by muse, mutect2, varscan2
- MEIS2 | c.159G>T p.A53= (on ENST00000561208 / NM_170675.5; = p.A40= on NM_002399.3) | Silent (SNP) | VAF 255/583 reads (44%) | catalogued as rs748998918, COSV54931781, COSV54940118, COSV99577268; called by muse, mutect2, varscan2
- MERTK | c.1743G>T p.V581= | Silent (SNP) | VAF 35/1199 reads (3%) | called by muse, mutect2
- MYH14 | c.867G>A p.S289= | Silent (SNP) | VAF 166/396 reads (42%) | called by muse, varscan2
- RIMS1 | c.3714G>A p.A1238= | Silent (SNP) | VAF 66/920 reads (7%) | catalogued as rs373917034; called by muse, mutect2
- UAP1L1 | c.394C>T p.L132= | Silent (SNP) | VAF 423/446 reads (95%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 40/1020 reads (4%) | called by muse, mutect2
- KIAA0586 | c.-120T>A | 5'UTR (SNP) | VAF 86/179 reads (48%) | called by muse, mutect2, varscan2
- NBN | c.1915-80dup | Intron (INS) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- PEG10 | c.*213C>A | 3'UTR (SNP) | VAF 292/596 reads (49%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81139711 C>T | 5'Flank (SNP) | VAF 134/267 reads (50%) | catalogued as rs997090902; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 32/284 reads (11%) | called by muse, varscan2
- USP9X | c.7062-80G>T | Intron (SNP) | VAF 92/211 reads (44%) | called by muse, mutect2, varscan2
